Somatic mutation profile of tumor specimen TCGA-S9-A7QX-01A (aliquot TCGA-S9-A7QX-01A-11D-A34A-08) from TCGA case TCGA-S9-A7QX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.5 years (13,332 days).
Specimen TCGA-S9-A7QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 256674f3-7146-4a8b-a287-3c8cdd618d5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7QX-10A (Blood Derived Normal), aliquot TCGA-S9-A7QX-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a07a5f5-90c0-47de-8d4f-693ea6e9f27e

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/105 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 49/61 reads (80%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.3479G>T p.R1160L (on ENST00000614293; = p.R1130L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55803385, COSV99686931; called by muse, mutect2, varscan2
- AC004922.1 | c.1088A>T p.E363V | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV53165035, COSV99402817; called by muse, mutect2, varscan2
- ADAMTSL1 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1038312943, COSV99441027; called by muse, varscan2
- BRSK1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100510311; called by muse, mutect2, varscan2
- C4BPA | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65537105; called by muse, mutect2, varscan2
- CACNA2D1 | c.2889T>A p.D963E (on ENST00000356253 / NM_001366867.1; = p.D951E on NM_000722.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100665911; called by muse, mutect2, varscan2
- FAM120C | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100069596, COSV60257769; called by muse, mutect2
- HCFC1 | c.2531C>T p.T844I | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100128448; called by muse, mutect2, varscan2
- KRT31 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV99289408; called by muse, mutect2, varscan2
- LRRC14 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99467059; called by muse, mutect2, varscan2
- MED12L | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777002012, COSV56372488; called by muse, mutect2, varscan2
- MUC16 | c.33987C>A p.D11329E | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.047); catalogued as COSV101198196, COSV67475802; called by muse, mutect2
- NUP42 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs751114640, COSV99330873; called by muse, mutect2, varscan2
- PRX | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs372473354; called by muse, mutect2, varscan2
- RAB19 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as rs745326291, COSV52045525; called by muse, mutect2, varscan2
- RABGAP1L | c.2429A>G p.Y810C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99267867; called by muse, mutect2, varscan2
- RGS12 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374800; called by muse, mutect2, varscan2
- SPINK7 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99199115; called by muse, mutect2, varscan2
- ZBBX | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100283132; called by muse, mutect2, varscan2
- ATRX | c.865del p.Q289Sfs*10 | Frame Shift Del (DEL) | VAF 108/324 reads (33%) | called by mutect2, pindel, varscan2
- STAT5B | c.2229C>T p.Y743= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99510650; called by muse, mutect2, varscan2
- STOX1 | c.1509A>G p.R503= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV100057544; called by muse, mutect2, varscan2
- TMEM236 | c.783C>T p.Y261= | Silent (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- TSKS | c.1527C>T p.H509= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs750484116, COSV99882934; called by muse, mutect2, varscan2
- ZBTB20 | c.1917C>T p.C639= (on ENST00000474710 / NM_001164342.2; = p.C566= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV100612752; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/60 reads (10%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- RREB1 | c.3809-5842T>A | Intron (SNP) | VAF 26/49 reads (53%) | catalogued as COSV100619140; called by muse, mutect2, varscan2
